Gene-level copy-number profile of tumor specimen ALCH-B3B2-TTP1-A from ALCHEMIST case ALCH-B3B2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.3 years (22,752 days).
Specimen ALCH-B3B2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c7f297a9-36ac-40d4-88ff-66a309ce8576.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3B2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/59770751-ac58-4939-8356-588065f3d494

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 893; copy number 2: 55,304; copy number 3: 2,086; copy number 4: 20; copy number 5: 24; copy number 6: 3; copy number 7: 23; copy number 9: 31.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr15:41,493,393–41,583,589, 5 genes: ITPKA, LTK, RPAP1, ELOCP2, TYRO3.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:14,301,389–14,331,067, 3 genes: MIR193BHG, MIR193B, MIR365A.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:31,465,543–31,465,832, 1 gene (within-gene range 0–2): RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,907,876–57,495,844, 13 genes, copy number 5: REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1.
- chr7:37,032–176,013, 7 genes, copy number 5: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2.
- chr16:2,339,150–2,426,699, 1 gene, copy number 5 (within-gene range 1–5): ABCA17P.
- chr19:1,086,574–1,174,268, 3 genes, copy number 5 (within-gene range 4–5): POLR2E, GPX4, SBNO2.
- chr19:27,793,431–30,713,538, 57 genes, copy number 6–9 (within-gene range 3–9): AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1.

Autosomal genes at a single copy (total copy number 1): 893. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
